MMRF case MMRF_2305 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5c8deb7b-1745-4d3f-a324-6e4fe89d2fc5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.3 years (24,948 days); ISS stage: III; Days to last known disease status: 803 days (2.2 years); Days to last follow up: 803 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 131 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 243 days; Days to treatment end: 243 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 2): M Protein 1.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 252 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.336 g/L; Beta 2 Microglobulin 8.67 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 8.65 ×10⁹/L; Platelets 403 ×10⁹/L; Creatinine 75 µmol/L; Calcium 2.56 mmol/L; Albumin 45.6 g/L; Total Protein 8.32 g/dL; Glucose 6.3 mmol/L.
- Day 89 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.663 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 52.3 mg/dL; Immunoglobulin G 9.14 g/L; Immunoglobulin A 0.691 g/L; Immunoglobulin M 0.315 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 13.2 ×10⁹/L; Absolute Neutrophil 9.23 ×10⁹/L; Platelets 529 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 7.61 mmol/L; Calcium 2.33 mmol/L; Albumin 36.5 g/L; Total Protein 6.11 g/dL; Glucose 4.6 mmol/L.
- Day 173 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.702 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 35.6 mg/dL; Immunoglobulin G 7.55 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 3.13 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.27 ×10⁹/L; Platelets 387 ×10⁹/L; Creatinine 62 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 2.49 mmol/L; Albumin 46.3 g/L; Total Protein 7.08 g/dL; Glucose 5.8 mmol/L.
- Day 275 (ECOG 2): Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 350 ×10⁹/L; Creatinine 62 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.39 mmol/L; Albumin 41.2 g/L; Total Protein 7.24 g/dL; Glucose 5.7 mmol/L.
- Day 365 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.762 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.68 mg/dL; Immunoglobulin G 8.65 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.469 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 336 ×10⁹/L; Creatinine 60 µmol/L; Calcium 2.37 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 6.1 mmol/L.
- Day 456 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.8 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.522 g/L; Beta 2 Microglobulin 1.91 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.62 ×10⁹/L; Absolute Neutrophil 4.91 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.9 mmol/L; Calcium 2.42 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 6 mmol/L.
- Day 540 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.83 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 1.91 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.9 mmol/L; Calcium 2.42 mmol/L; Albumin 46.6 g/L; Total Protein 7.13 g/dL; Glucose 6 mmol/L.
- Day 624 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.7 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 2.09 g/L; Immunoglobulin M 0.902 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.55 ×10⁹/L; Absolute Neutrophil 5.62 ×10⁹/L; Platelets 352 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 6.6 mmol/L; Calcium 2.28 mmol/L; Albumin 42.7 g/L; Total Protein 7.1 g/dL; Glucose 6 mmol/L.
- Day 712 (ECOG 0): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.27 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 2.41 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 3.21 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 8.44 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 65 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.31 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.5 mmol/L.
- Day 803 (ECOG 1): M Protein 0.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.66 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 2.52 g/L; Immunoglobulin M 0.58 g/L; Beta 2 Microglobulin 7.04 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 425 ×10⁹/L; Creatinine 70 µmol/L; Calcium 2.42 mmol/L; Albumin 40.5 g/L; Total Protein 7.29 g/dL; Glucose 5.7 mmol/L.

Other clinical attributes
- Day -5: Weight: 95 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2305_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2305_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
